Somatic mutation profile of cancer-model specimen HCM-CSHL-0835-C20-85N (3D Organoid, passage 5; aliquot HCM-CSHL-0835-C20-85N-01D-A85L-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0835-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 61.2 years (22,358 days).
Specimen HCM-CSHL-0835-C20-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e974926b-d273-4e84-9fbf-ec44c5c367d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0835-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0835-C20-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e9bf011-a74b-425a-a61d-0d0c8cdd414a

The open-access MAF lists 180 somatic variants for this specimen: 135 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 40, Frame Shift Del 10, Nonsense Mutation 8, Frame Shift Ins 6, RNA 3, Splice Region 3, Intron 2, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 143/303 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 132/288 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC19A3 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 161/321 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980641322, COSV99295555; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.407A>T p.Q136L | Missense Mutation (SNP) | VAF 143/365 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52751724, COSV52782611, COSV52910696, COSV53122800; called by muse, mutect2, varscan2
- AICDA | c.159C>T p.N53= | Splice Region (SNP) | VAF 89/177 reads (50%) | catalogued as COSV57565481; called by muse, mutect2, varscan2
- AL136295.1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 152/355 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs138817054; called by muse, mutect2, varscan2
- APC | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 144/272 reads (53%) | catalogued as COSV57323670, COSV57328904, COSV57399512; called by muse, mutect2, varscan2
- APLP1 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 117/229 reads (51%) | catalogued as rs372591248; called by muse, mutect2, varscan2
- ARHGEF33 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 184/378 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.105); catalogued as rs891432113, COSV67256660; called by muse, mutect2, varscan2
- ASB18 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 200/327 reads (61%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1299574392; called by muse, mutect2, varscan2
- CD1B | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.367); catalogued as rs757815693, COSV63804341; called by muse, mutect2, varscan2
- CDH12 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 283/390 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377660503; called by muse, mutect2, varscan2
- CLDN18 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs748597305; called by muse, mutect2, varscan2
- CPEB1 | c.34dup p.C12Lfs*9 | Frame Shift Ins (INS) | VAF 295/476 reads (62%) | catalogued as rs1271064291; called by mutect2, varscan2
- DGKQ | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 196/423 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs147014854, COSV56616367; called by muse, mutect2, varscan2
- DPEP3 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 145/293 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs181650862; called by muse, mutect2, varscan2
- DUSP26 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 265/404 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1315129621, COSV99823492; called by muse, mutect2, varscan2
- EML5 | c.3877G>A p.G1293S | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61341958; called by muse, mutect2, varscan2
- EZHIP | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 238/245 reads (97%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1231114385; called by muse, mutect2, varscan2
- FAM126A | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 320/486 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs574238934; called by muse, mutect2, varscan2
- FAM180A | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs890848627, COSV100647213; called by muse, mutect2, varscan2
- FFAR1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 223/457 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs768739078; called by muse, mutect2, varscan2
- FREM2 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 194/644 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs774024998; called by muse, mutect2, varscan2
- HERC2 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 204/441 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs201542966, COSV55321457; called by muse, mutect2, varscan2
- HRH2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 185/384 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1396794379, COSV99199543; called by muse, mutect2, varscan2
- IAPP | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 173/335 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs761079012, COSV53714105; called by muse, mutect2, varscan2
- INS | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 99/234 reads (42%) | catalogued as COSV99059779; called by muse, mutect2, varscan2
- INTS1 | c.4030C>T p.R1344W | Missense Mutation (SNP) | VAF 100/673 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs372228066; called by muse, mutect2, varscan2
- INTS6 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 138/484 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778184413; called by muse, mutect2, varscan2
- IPMK | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 125/246 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.396); catalogued as rs139982255; called by muse, mutect2, varscan2
- JARID2 | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59185079; called by muse, mutect2, varscan2
- KCNQ5 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 174/351 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs777062053, COSV59649876; called by muse, mutect2, varscan2
- KDM5A | c.4261C>T p.R1421W | Missense Mutation (SNP) | VAF 142/257 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1385893760; called by muse, mutect2, varscan2
- KIF2B | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 181/345 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457562898, COSV52129186, COSV52132583, COSV52133299; called by muse, mutect2, varscan2
- KLF10 | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 319/500 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs1177113992; called by muse, mutect2, varscan2
- KLHL13 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53245411; called by muse, mutect2
- KLHL32 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 10/330 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100987486; called by muse, mutect2
- LIPI | c.758G>C p.G253A | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60708335; called by muse, mutect2, varscan2
- LIPI | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143577177; called by muse, mutect2, varscan2
- MADD | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 208/423 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.991); catalogued as rs751993844, COSV60629198; called by muse, mutect2, varscan2
- MDGA2 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 211/426 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs748391283, COSV67811984; called by muse, mutect2, varscan2
- NDST2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 156/318 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as rs757075560; called by muse, mutect2, varscan2
- NID1 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 270/593 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as COSV99938227; called by muse, mutect2, varscan2
- NLRP5 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 132/276 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV66763903; called by muse, mutect2, varscan2
- NOTO | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 156/351 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV68260172; called by muse, mutect2, varscan2
- NXPE1 | c.751C>A p.P251T (on ENST00000424269; = p.P109T on NM_152315.5) | Missense Mutation (SNP) | VAF 143/315 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs752983703; called by muse, mutect2, varscan2
- OR2M5 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 151/353 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs552526523, COSV63545928; called by muse, mutect2, varscan2
- OR2T27 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 161/422 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs758144601; called by muse, mutect2, varscan2
- OSMR | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 151/652 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as rs370592814, COSV57086124; called by muse, mutect2, varscan2
- PCDHA13 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 216/486 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV56508960; called by muse, mutect2, varscan2
- PCDHB4 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 365/728 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs782064797, COSV52028091, COSV99521960; called by muse, mutect2, varscan2
- PHRF1 | c.2716C>T p.R906W (on ENST00000264555 / NM_001286581.2; = p.R905W on NM_020901.4) | Missense Mutation (SNP) | VAF 324/673 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1016832683, COSV52760435; called by muse, mutect2, varscan2
- POM121L12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 478/736 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200929126, COSV68692625; called by muse, mutect2, varscan2
- PRDM9 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 556/860 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs764241201, COSV57010337, COSV57015844; called by muse, varscan2
- PSG6 | c.458G>C p.S153T | Missense Mutation (SNP) | VAF 119/239 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV51833396; called by muse, mutect2, varscan2
- RAB11FIP3 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 128/370 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs17846475; called by muse, mutect2, varscan2
- RBMXL3 | c.2830G>A p.G944R | Missense Mutation (SNP) | VAF 201/203 reads (99%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.98); catalogued as rs1032225014, COSV57757118; called by muse, mutect2, varscan2
- RGR | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs201335015, COSV100812996, COSV63893643; called by muse, mutect2, varscan2
- RP1L1 | c.4673C>T p.A1558V | Missense Mutation (SNP) | VAF 215/629 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as rs751542131; called by muse, mutect2, varscan2
- RTF1 | c.1206C>T p.V402= | Splice Region (SNP) | VAF 96/201 reads (48%) | catalogued as rs774225957; called by muse, mutect2, varscan2
- SCG2 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 197/422 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as rs1163614408, COSV100544671, COSV59540102; called by muse, mutect2, varscan2
- SCN11A | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 184/358 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776182932, COSV56579054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SENP3 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 146/290 reads (50%) | catalogued as rs1281145992, COSV53435722, COSV99547827; called by muse, mutect2, varscan2
- SOHLH2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 152/430 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750638861, COSV65901195; called by muse, mutect2, varscan2
- TCF7L2 | c.468G>A p.W156* (on ENST00000355995 / NM_001367943.1; = p.W133* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 114/279 reads (41%) | catalogued as COSV100588727; called by muse, mutect2, varscan2
- TDRD15 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 149/285 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385396546, COSV68267170; called by muse, mutect2, varscan2
- TDRD9 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 179/463 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs569772232; called by muse, mutect2, varscan2
- TEX15 | c.5122dup p.R1708Kfs*6 (on ENST00000256246; = p.R2091Kfs*6 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 276/473 reads (58%) | catalogued as rs778104055; called by mutect2, varscan2
- TNFSF14 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 227/421 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs200572645; called by muse, mutect2, varscan2
- TRIM46 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs768491601; called by muse, mutect2, varscan2
- USP8 | c.1990G>C p.G664R | Missense Mutation (SNP) | VAF 128/278 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV56163873; called by muse, mutect2, varscan2
- UTRN | c.6802C>T p.R2268* | Nonsense Mutation (SNP) | VAF 133/267 reads (50%) | catalogued as rs755543767, COSV100839969; called by muse, mutect2, varscan2
- XPO5 | c.651G>A p.A217= | Splice Region (SNP) | VAF 221/221 reads (100%) | catalogued as rs765845766, COSV54828311; called by muse, mutect2, varscan2
- YTHDF1 | c.773del p.G258Vfs*8 | Frame Shift Del (DEL) | VAF 206/699 reads (29%) | catalogued as rs1234547092, COSV64833859; called by mutect2, pindel, varscan2
- ZCCHC14 | c.1562C>T p.A521V (on ENST00000268616; = p.A658V on NM_015144.3) | Missense Mutation (SNP) | VAF 206/457 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); catalogued as rs375771674; called by muse, mutect2, varscan2
- ZHX2 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 241/735 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs759251479, COSV58714307; called by muse, mutect2, varscan2
- AC004593.2 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 122/453 reads (27%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPP | c.1229A>C p.Y410S | Missense Mutation (SNP) | VAF 170/489 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ANTXRL | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AOAH | c.194C>G p.S65W | Missense Mutation (SNP) | VAF 164/537 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- ASIC5 | c.385_392del p.F129Mfs*21 | Frame Shift Del (DEL) | VAF 117/292 reads (40%) | called by mutect2, pindel, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 164/454 reads (36%) | called by pindel, varscan2
- C10orf71 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2
- C10orf90 | c.1585A>G p.S529G | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- C8orf34 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 237/733 reads (32%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- COL4A6 | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 182/205 reads (89%) | called by muse, mutect2, varscan2
- CYP2U1 | c.1166del p.N389Tfs*25 | Frame Shift Del (DEL) | VAF 152/375 reads (41%) | called by mutect2, pindel, varscan2
- DIS3L2 | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DYNC2I1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 123/361 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- EBF1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- EZH1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 96/182 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FOXE1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 10/330 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GABRB3 | c.806A>T p.Y269F | Missense Mutation (SNP) | VAF 146/286 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GIMAP8 | c.1062del p.K354Nfs*6 | Frame Shift Del (DEL) | VAF 248/463 reads (54%) | called by mutect2, pindel, varscan2
- GOLGA4 | c.4415A>T p.K1472M | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- HFM1 | c.860_861delinsT p.K287Mfs*14 | Frame Shift Del (DEL) | VAF 33/167 reads (20%) | called by pindel, varscan2*
- HNRNPA2B1 | c.797_800dup p.G268Rfs*22 (on ENST00000354667 / NM_031243.3; = p.G256Rfs*22 on NM_002137.4) | Frame Shift Ins (INS) | VAF 251/412 reads (61%) | called by mutect2, pindel, varscan2
- HOXA10 | c.67_68del p.S23Pfs*67 | Frame Shift Del (DEL) | VAF 171/692 reads (25%) | called by pindel, varscan2
- IBA57 | c.680-1G>A p.X227_splice | Splice Site (SNP) | VAF 98/222 reads (44%) | called by muse, mutect2, varscan2
- KLF10 | c.1391T>G p.V464G | Missense Mutation (SNP) | VAF 316/498 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- LIMA1 | c.1405A>T p.N469Y | Missense Mutation (SNP) | VAF 176/378 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- MAD1L1 | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 237/782 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- MAGI2 | c.1292dup p.S432Efs*16 | Frame Shift Ins (INS) | VAF 167/615 reads (27%) | called by mutect2, pindel, varscan2
- ME3 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 107/229 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MSX1 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 255/478 reads (53%) | called by muse, mutect2, varscan2
- MTIF2 | c.2139A>T p.E713D | Missense Mutation (SNP) | VAF 132/304 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MUC16 | c.22397C>A p.T7466K | Missense Mutation (SNP) | VAF 170/383 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NADK | c.1199C>A p.T400N | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NTNG1 | c.446T>A p.V149D | Missense Mutation (SNP) | VAF 176/376 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OR5V1 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 119/316 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- OR8H1 | c.298A>T p.M100L | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- OSBPL6 | c.1278del p.L427Cfs*11 | Frame Shift Del (DEL) | VAF 116/265 reads (44%) | called by mutect2, pindel, varscan2
- PCDHB12 | c.517A>G p.N173D | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PEG3 | c.1835C>A p.P612Q | Missense Mutation (SNP) | VAF 200/426 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PLCH1 | c.155G>C p.R52P (on ENST00000340059 / NM_001130960.2; = p.R64P on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PNMA3 | c.872A>T p.Q291L | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBM25 | c.2103A>T p.E701D | Missense Mutation (SNP) | VAF 138/280 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RHOC | c.134A>T p.D45V | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- RHOC | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 99/282 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- RNF182 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- RYK | c.1734G>C p.M578I (on ENST00000620660 / NM_001005861.2; = p.M575I on NM_002958.4) | Missense Mutation (SNP) | VAF 119/267 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SACS | c.11250T>A p.N3750K | Missense Mutation (SNP) | VAF 176/508 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SERPINA10 | c.1178G>T p.R393M | Missense Mutation (SNP) | VAF 173/351 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- SIPA1 | c.2873_2903+1del | Frame Shift Del (DEL) | VAF 85/287 reads (30%) | called by mutect2, pindel, varscan2
- SLC26A5 | c.352del p.Y118Tfs*17 | Frame Shift Del (DEL) | VAF 127/431 reads (29%) | called by mutect2, pindel, varscan2
- SOX9 | c.1385dup p.Y463Lfs*115 | Frame Shift Ins (INS) | VAF 442/618 reads (72%) | called by mutect2, pindel, varscan2
- TEX44 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 206/394 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMEM237 | c.637A>G p.T213A (on ENST00000409883 / NM_001044385.3; = p.T205A on NM_152388.4) | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TOMM20 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- TRIM27 | c.780A>C p.R260S | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- TRPC4 | c.2747C>A p.T916K (on ENST00000379705 / NM_016179.4; = p.T921K on NM_003306.3) | Missense Mutation (SNP) | VAF 132/358 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPM3 | c.2309G>T p.R770L (on ENST00000357533 / NM_001366142.2; = p.R613L on NM_020952.6) | Missense Mutation (SNP) | VAF 148/312 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- USP8 | c.1559_1560dup p.A521Kfs*29 | Frame Shift Ins (INS) | VAF 120/268 reads (45%) | called by mutect2, pindel, varscan2
- XRN2 | c.1283A>G p.D428G | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN12 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ARHGEF19 | c.1992C>T p.P664= | Silent (SNP) | VAF 218/219 reads (100%) | catalogued as rs151051853, COSV99580312; called by muse, mutect2, varscan2
- BRD4 | c.3705G>A p.E1235= | Silent (SNP) | VAF 185/425 reads (44%) | catalogued as rs201653061, COSV54589780; called by muse, mutect2, varscan2
- C10orf71 | c.4113C>T p.R1371= | Silent (SNP) | VAF 256/490 reads (52%) | catalogued as rs1242522499, COSV60506696; called by muse, mutect2, varscan2
- CCDC136 | c.3426G>A p.S1142= | Silent (SNP) | VAF 278/458 reads (61%) | catalogued as COSV52802604; called by muse, mutect2, varscan2
- CFTR | c.2835G>A p.S945= | Silent (SNP) | VAF 138/416 reads (33%) | catalogued as rs193922513, COSV50081176; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- DPYSL3 | c.894G>A p.A298= | Silent (SNP) | VAF 174/376 reads (46%) | catalogued as rs200777055, COSV58331098; called by muse, mutect2, varscan2
- EIF4G1 | c.3531G>A p.A1177= (on ENST00000346169 / NM_198241.3; = p.A982= on NM_004953.5) | Silent (SNP) | VAF 165/363 reads (45%) | catalogued as rs763154760, COSV59991267; called by muse, mutect2, varscan2
- FAT4 | c.300C>T p.S100= | Silent (SNP) | VAF 236/513 reads (46%) | called by muse, mutect2, varscan2
- FLT3 | c.579C>T p.I193= | Silent (SNP) | VAF 124/391 reads (32%) | catalogued as rs775998708; called by muse, mutect2, varscan2
- GABPA | c.558C>T p.P186= | Silent (SNP) | VAF 77/175 reads (44%) | called by muse, mutect2, varscan2
- GABRE | c.306C>T p.S102= | Silent (SNP) | VAF 176/176 reads (100%) | catalogued as rs375575457; called by muse, mutect2, varscan2
- GPR87 | c.939T>C p.I313= | Silent (SNP) | VAF 160/343 reads (47%) | called by muse, mutect2, varscan2
- IGLV2-14 | c.81C>T p.A27= | Silent (SNP) | VAF 165/367 reads (45%) | catalogued as rs552858399; called by muse, mutect2, varscan2
- INHBA | c.258G>A p.A86= | Silent (SNP) | VAF 178/556 reads (32%) | catalogued as rs780556409, COSV54219416, COSV54225307, COSV54225743; called by muse, mutect2, varscan2
- INTS6 | c.1827A>T p.P609= | Silent (SNP) | VAF 135/480 reads (28%) | called by muse, mutect2, varscan2
- ITGB2 | c.1602G>A p.G534= (on ENST00000302347; = p.G510= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/468 reads (6%) | called by muse, mutect2
- JADE2 | c.1644C>T p.S548= | Silent (SNP) | VAF 89/393 reads (23%) | catalogued as rs746185076; called by muse, mutect2, varscan2
- KAT14 | c.1407G>A p.K469= | Silent (SNP) | VAF 384/554 reads (69%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.75G>A p.S25= | Silent (SNP) | VAF 127/302 reads (42%) | catalogued as rs1267777001, COSV55430587; called by muse, mutect2, varscan2
- KLHL1 | c.2199G>A p.L733= | Silent (SNP) | VAF 107/369 reads (29%) | catalogued as COSV64770258; called by muse, mutect2, varscan2
- LAP3 | c.42C>G p.V14= | Silent (SNP) | VAF 157/327 reads (48%) | called by muse, mutect2, varscan2
- LMTK3 | c.3984G>C p.G1328= | Silent (SNP) | VAF 237/511 reads (46%) | called by muse, mutect2, varscan2
- NFATC1 | c.1083G>A p.P361= | Silent (SNP) | VAF 447/450 reads (99%) | catalogued as rs370647787; called by muse, mutect2, varscan2
- NRG1 | c.132C>T p.P44= (on ENST00000523534; = p.P191= on NM_013962.2) | Silent (SNP) | VAF 196/646 reads (30%) | catalogued as rs199760025, COSV101584785, COSV73066588; called by muse, mutect2, varscan2
- OR4C12 | c.258G>A p.E86= | Silent (SNP) | VAF 105/260 reads (40%) | catalogued as COSV58859987; called by muse, varscan2
- PPFIA2 | c.906A>G p.E302= | Silent (SNP) | VAF 158/335 reads (47%) | called by muse, mutect2, varscan2
- PRDM6 | c.537C>A p.G179= | Silent (SNP) | VAF 162/346 reads (47%) | called by muse, mutect2, varscan2
- PXDN | c.2688C>T p.S896= | Silent (SNP) | VAF 174/367 reads (47%) | catalogued as rs747948602, COSV53240194; called by muse, mutect2, varscan2
- RIOK3 | c.588A>G p.L196= | Silent (SNP) | VAF 278/279 reads (100%) | called by muse, mutect2, varscan2
- RNF182 | c.738T>A p.P246= | Silent (SNP) | VAF 10/246 reads (4%) | called by muse, mutect2
- RREB1 | c.1455T>C p.S485= | Silent (SNP) | VAF 130/452 reads (29%) | catalogued as rs750011164; called by muse, mutect2, varscan2
- SLC12A3 | c.2898C>T p.Y966= (on ENST00000563236 / NM_001126108.2; = p.Y975= on NM_000339.3) | Silent (SNP) | VAF 90/177 reads (51%) | called by muse, varscan2
- SMARCA2 | c.1017C>T p.P339= | Silent (SNP) | VAF 167/317 reads (53%) | catalogued as rs750120946, COSV61804287; called by muse, mutect2, varscan2
- SON | c.2037A>C p.T679= | Silent (SNP) | VAF 176/341 reads (52%) | called by muse, mutect2, varscan2
- SPTB | c.1785C>T p.T595= | Silent (SNP) | VAF 89/192 reads (46%) | catalogued as rs552724363, COSV67630278; called by muse, mutect2, varscan2
- TCP11L1 | c.1266C>T p.T422= | Silent (SNP) | VAF 170/370 reads (46%) | catalogued as rs756467493, COSV57514872; called by muse, mutect2, varscan2
- TNXB | c.5157G>A p.P1719= (on ENST00000647633; = p.P1472= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 365/365 reads (100%) | catalogued as rs777358881; called by muse, mutect2, varscan2
- TTYH3 | c.523C>T p.L175= | Silent (SNP) | VAF 147/579 reads (25%) | catalogued as rs1268808588; called by muse, mutect2, varscan2
- UBR5 | c.4203A>G p.L1401= | Silent (SNP) | VAF 70/247 reads (28%) | catalogued as rs750675912; called by muse, mutect2, varscan2
- ZNF469 | c.9003C>T p.D3001= (on ENST00000437464; = p.D3029= on NM_001367624.2) | Silent (SNP) | VAF 229/475 reads (48%) | catalogued as rs780843955, COSV71258309; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCL7 | c.77-12G>T | Intron (SNP) | VAF 201/407 reads (49%) | called by muse, mutect2, varscan2
- DCHS2 | n.8682G>A | RNA (SNP) | VAF 116/294 reads (39%) | catalogued as COSV61775889; called by muse, mutect2, varscan2
- FAM21FP | n.299C>A | RNA (SNP) | VAF 93/270 reads (34%) | catalogued as rs1402648395; called by muse, mutect2, varscan2
- MASP1 | c.1303+5315G>A | Intron (SNP) | VAF 206/404 reads (51%) | catalogued as rs765087753; called by muse, mutect2, varscan2
- MIR100HG | n.244G>T | RNA (SNP) | VAF 175/316 reads (55%) | called by muse, mutect2, varscan2
